Somatic mutation profile of tumor specimen MMRF_1520_1_BM_CD138pos (aliquot MMRF_1520_1_BM_CD138pos_T1_KBS5U_L05544) from MMRF case MMRF_1520, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.4 years (22,782 days).
Specimen MMRF_1520_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f16a64f-37ce-4110-ac03-a5a7995a3f8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1520_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1520_1_PB_Whole_C3_KBS5U_L05564; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94c4a570-7e5e-4f6c-8144-1c1c763c187a

The open-access MAF lists 113 somatic variants for this specimen: 47 protein-altering or splice-affecting, 13 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 27, Intron 16, Silent 13, 5'UTR 7, Nonsense Mutation 3, RNA 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOOL | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 53/57 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765221837, COSV60578194; called by muse, mutect2, varscan2
- CDH20 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs776559067; called by muse, mutect2, varscan2
- CDH7 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752537638; called by muse, mutect2, varscan2
- DOCK1 | c.5249G>A p.G1750E | Missense Mutation (SNP) | VAF 108/189 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1457947484; called by muse, mutect2, varscan2
- ETV5 | c.738A>T p.Q246H | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.934); catalogued as COSV60500432, COSV60505741; called by muse, mutect2, varscan2
- FAM53A | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs199989747; called by muse, mutect2, varscan2
- H4C9 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs1270976284, COSV62890277; called by muse, mutect2, varscan2
- IGHJ5 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 27/55 reads (49%) | PolyPhen benign (0.003); catalogued as rs782494105; called by muse, mutect2, varscan2
- JAKMIP2 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 18/207 reads (9%) | catalogued as rs373933909, COSV54611275; called by muse, mutect2
- MSH4 | c.632T>C p.M211T | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs369156759; called by muse, mutect2, varscan2
- MYO16 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 83/88 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99193817; called by muse, mutect2, varscan2
- NUBP2 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1397797591, COSV51904826; called by muse, mutect2, varscan2
- PLEC | c.1850G>A p.R617H (on ENST00000322810 / NM_201380.4; = p.R507H on NM_000445.5) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781886606, COSV59603393; called by muse, mutect2, varscan2
- SAMD9 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1159455564; called by muse, mutect2
- SYNJ2 | c.3617C>T p.S1206F | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.007); catalogued as rs747473553; called by muse, mutect2, varscan2
- THRAP3 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 81/145 reads (56%) | catalogued as COSV100663138; called by muse, mutect2, varscan2
- TMEM125 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs762495775, COSV71326972; called by muse, mutect2, varscan2
- UBE2O | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1567861452; called by muse, mutect2, varscan2
- VWA8 | c.666dup p.E223Rfs*11 | Frame Shift Ins (INS) | VAF 17/59 reads (29%) | catalogued as rs751039053; called by mutect2, pindel, varscan2
- ZNF711 | c.1574G>A p.R525K | Missense Mutation (SNP) | VAF 30/31 reads (97%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV99341730; called by muse, mutect2, varscan2
- AL121845.3 | c.793T>A p.C265S | Missense Mutation (SNP) | VAF 61/129 reads (47%) | called by muse, mutect2, varscan2
- CADM2 | c.5T>A p.I2N | Missense Mutation (SNP) | VAF 163/471 reads (35%) | SIFT tolerated, low confidence (0.48); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- CCDC57 | c.299C>G p.A100G | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DGAT2L6 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- EFNB2 | c.105G>A p.W35* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- FAM199X | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.136); called by muse, mutect2
- GLIS3 | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HEXA | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAPK8 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.181); called by muse, mutect2
- MAST2 | c.2084A>G p.E695G | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MET | c.2182T>G p.L728V | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.601); called by muse, mutect2
- NMNAT3 | c.320C>G p.S107C (on ENST00000296202 / NM_001320512.1; = p.S70C on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- NOX5 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- PSMA7 | c.332T>C p.I111T | Missense Mutation (SNP) | VAF 90/164 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- REST | c.1969G>T p.V657F | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RRM2 | c.93G>C p.E31D | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SIGLEC1 | c.2644C>G p.L882V | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- STARD3NL | c.227T>G p.V76G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2
- STARD9 | c.4151A>T p.K1384M | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- STARD9 | c.9256G>A p.E3086K | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- STT3B | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC39C | c.1129G>A p.E377K (on ENST00000317571 / NM_001135993.2; = p.E316K on NM_153211.4) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.015); called by muse, mutect2
- TXNDC5 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- UNC45B | c.769A>G p.K257E | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- ZNF200 | c.52A>G p.I18V | Missense Mutation (SNP) | VAF 97/217 reads (45%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF480 | c.341C>A p.A114E | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2
- ZNF667 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- ASXL3 | c.787T>C p.L263= | Silent (SNP) | VAF 57/236 reads (24%) | called by muse, mutect2, varscan2
- H2AC11 | c.150G>C p.V50= | Silent (SNP) | VAF 52/91 reads (57%) | called by muse, mutect2, varscan2
- IGHJ5 | c.12C>T p.D4= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs782386479; called by muse, mutect2, varscan2
- LIPT2 | c.30C>A p.R10= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV59526586; called by muse, mutect2, varscan2
- LRRC27 | c.768G>A p.E256= | Silent (SNP) | VAF 9/131 reads (7%) | catalogued as rs1200275937; called by muse, mutect2
- PTCHD1 | c.2379G>T p.V793= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- RC3H2 | c.2322G>A p.Q774= | Silent (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- RHBDL3 | c.1011C>T p.H337= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs765120634; called by muse, mutect2
- SMOC2 | c.531G>A p.A177= (on ENST00000356284 / NM_001166412.2; = p.A188= on NM_022138.3) | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs769942349; called by muse, mutect2, varscan2
- STAT5A | c.564G>A p.Q188= | Silent (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- SYMPK | c.372C>T p.N124= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs766252934; called by muse, mutect2, varscan2
- VCPIP1 | c.750G>A p.L250= | Silent (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- ZNF516 | c.3216C>A p.L1072= | Silent (SNP) | VAF 68/98 reads (69%) | catalogued as rs1251864514; called by muse, mutect2, varscan2
- BIRC3 | c.-2418del | 5'UTR (DEL) | VAF 36/102 reads (35%) | called by mutect2, pindel, varscan2
- C5orf60 | n.2161C>T | RNA (SNP) | VAF 25/49 reads (51%) | catalogued as rs1434380189; called by muse, mutect2, varscan2
- CERS6 | c.*1868A>G | 3'UTR (SNP) | VAF 62/81 reads (77%) | called by muse, mutect2, varscan2
- CFLAR | c.523+803A>G | Intron (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- CLEC4D | c.*914C>T | 3'UTR (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- CLEC5A | c.*2242G>C | 3'UTR (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- COL14A1 | c.1597+1437G>T | Intron (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- COL4A3 | c.1409-73G>A | Intron (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2
- CXCR1 | c.*1144C>T | 3'UTR (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
- DBN1 | c.*411G>T | 3'UTR (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- DTHD1 | c.*869G>A | 3'UTR (SNP) | VAF 54/97 reads (56%) | called by muse, mutect2, varscan2
- EPB42 | c.655-43G>T | Intron (SNP) | VAF 37/72 reads (51%) | called by muse, mutect2, varscan2
- GPD1L | c.*368G>A | 3'UTR (SNP) | VAF 37/64 reads (58%) | called by muse, mutect2
- HELLPAR | n.198655C>T | RNA (SNP) | VAF 30/55 reads (55%) | called by muse, mutect2, varscan2
- KCNH2 | c.1128+1859G>T | Intron (SNP) | VAF 12/35 reads (34%) | catalogued as rs1474806574; called by muse, mutect2, varscan2
- KDM7A | c.*1885C>T | 3'UTR (SNP) | VAF 36/94 reads (38%) | catalogued as rs1048529840; called by muse, mutect2, varscan2
- MATN3 | c.*1049T>A | 3'UTR (SNP) | VAF 20/59 reads (34%) | called by muse, varscan2
- MDH2 | c.885+69A>C | Intron (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2
- MEAF6 | c.90+94C>G | Intron (SNP) | VAF 5/75 reads (7%) | catalogued as rs1012083171; called by muse, mutect2
- MRAS | c.*1395G>A | 3'UTR (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- NAAA | c.969+547A>G | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- NOXA1 | c.-16G>A | 5'UTR (SNP) | VAF 5/29 reads (17%) | catalogued as rs1477298604; called by muse, mutect2, varscan2
- OSBPL10 | c.*2618C>A | 3'UTR (SNP) | VAF 8/42 reads (19%) | catalogued as rs1253497408; called by muse, mutect2
- OXSR1 | c.*2332A>G | 3'UTR (SNP) | VAF 9/68 reads (13%) | called by mutect2, varscan2
- PCDHGA3 | c.2425-66619G>A | Intron (SNP) | VAF 4/70 reads (6%) | catalogued as rs1023078587; called by muse, mutect2
- PCMT1 | c.*778T>A | 3'UTR (SNP) | VAF 37/72 reads (51%) | called by muse, mutect2, varscan2
- PDE10A | c.*4950G>T | 3'UTR (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2, varscan2
- PICALM | c.-42C>T | 5'UTR (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- PLA2G2C | c.*1301G>A | 3'UTR (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- PRC1 | c.268-105T>C | Intron (SNP) | VAF 3/14 reads (21%) | catalogued as rs1050373762; called by muse, mutect2
- PRRG3 | c.*2094G>A | 3'UTR (SNP) | VAF 48/50 reads (96%) | called by muse, mutect2, varscan2
- R3HCC1 | c.1313-356T>A | Intron (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- RETNLB | c.-52T>A | 5'UTR (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- RIMS2 | c.698+52928G>A | Intron (SNP) | VAF 122/265 reads (46%) | catalogued as rs754952631; called by muse, mutect2, varscan2
- RNF152 | c.*7080G>T | 3'UTR (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- RTP1 | c.-26G>T | 5'UTR (SNP) | VAF 53/237 reads (22%) | called by muse, mutect2, varscan2
- SCP2 | c.1081+5798G>A | Intron (SNP) | VAF 96/179 reads (54%) | catalogued as rs527480575; called by muse, mutect2
- SIM1 | chr6:100385747 T>C | 3'Flank (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- SLC12A1 | c.628+2074T>A | Intron (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- SLC25A27 | c.*261G>A | 3'UTR (SNP) | VAF 10/175 reads (6%) | catalogued as rs950627156; called by muse, mutect2
- SLC35F6 | c.*780G>C | 3'UTR (SNP) | VAF 16/91 reads (18%) | called by mutect2, varscan2
- SNAPC5 | c.*218A>T | 3'UTR (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- SRFBP1 | c.-57C>G | 5'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2
- ST6GAL2 | c.*3036G>C | 3'UTR (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- SUCO | c.*743G>A | 3'UTR (SNP) | VAF 125/170 reads (74%) | called by muse, mutect2, varscan2
- TBC1D10C | c.649-13G>A | Intron (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- TMEM254 | c.*1371C>T | 3'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- TSPAN2 | c.*548C>A | 3'UTR (SNP) | VAF 38/86 reads (44%) | called by muse, mutect2, varscan2
- TTR | c.-21A>T | 5'UTR (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- TXNDC9 | c.*386T>G | 3'UTR (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- UNC5D | c.104-4794C>T | Intron (SNP) | VAF 77/175 reads (44%) | catalogued as rs202067719, COSV99778679; called by muse, mutect2, varscan2
- WASF3 | c.*826G>T | 3'UTR (SNP) | VAF 66/71 reads (93%) | called by muse, mutect2, varscan2
- ZNF280C | c.*476G>T | 3'UTR (SNP) | VAF 44/47 reads (94%) | called by muse, mutect2, varscan2
